Gene-level copy-number profile of tumor specimen TCGA-UC-A7PD-01A from TCGA case TCGA-UC-A7PD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 21.5 years (7,855 days).
Specimen TCGA-UC-A7PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.04f4e35d-a0d5-4254-9407-0b42427c4a4e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UC-A7PD-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/19a1942c-06ad-48eb-96fd-b6a780f9b062

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,647; copy number 2: 51,717; copy number 3: 3,961; copy number 4: 82; copy number 5: 93; copy number 6: 55; copy number 8: 148; copy number 10: 10; copy number 12: 49; copy number 13: 2; copy number 14: 8; copy number 23: 1; copy number 31: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UC-A7PD-01A-11D-A350-01): tumor purity 0.66, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 410 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:16,316,324–21,970,959, 77 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:167,954,020–168,913,371, 10 genes, copy number 5 (within-gene range 2–5): STK39, PHF5GP, RN7SL813P, CERS6, MIR4774, RNU6-766P, CERS6-AS1, NOSTRIN, SPC25, G6PC2.
- chr2:172,735,274–180,939,298, 160 genes, copy number 5–10 (broad region; genes not listed).
- chr2:181,076,051–183,161,680, 31 genes, copy number 6 (within-gene range 3–6): AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35.
- chr2:184,593,577–187,003,377, 23 genes, copy number 6: AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7.
- chr11:84,545,131–85,021,655, 8 genes, copy number 14: HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6.
- chr11:94,543,840–102,874,982, 101 genes, copy number 10–31 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,647. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
